Somatic mutation profile of tumor specimen ALCH-AEPS-TTP1-A (aliquot ALCH-AEPS-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AEPS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.8 years (24,770 days).
Specimen ALCH-AEPS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1acec43c-becf-4a37-91f3-8b0ee63e5c61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEPS-NB1-A (Blood Derived Normal), aliquot ALCH-AEPS-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/020ac9f0-7686-4a54-abdd-ec8b9c033944

The open-access MAF lists 68 somatic variants for this specimen: 43 protein-altering or splice-affecting, 20 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 20, Splice Site 3, Frame Shift Del 2, 3'UTR 2, Splice Region 2, Intron 2, Nonsense Mutation 1, In Frame Ins 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 217/778 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ATP10D | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 74/521 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56704013; called by muse, mutect2, varscan2
- ATP12A | c.2320G>A p.V774I | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as rs779518377, COSV104374431, COSV54512595; called by muse, mutect2, varscan2
- CYP19A1 | c.1038G>T p.K346N | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV53061153; called by muse, mutect2
- CYP27B1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); catalogued as rs180727885; called by muse, mutect2, varscan2
- CYP4F8 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 62/221 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as rs558107890, COSV57853829; called by muse, mutect2, varscan2
- DENND2A | c.2827C>T p.R943C | Missense Mutation (SNP) | VAF 89/365 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1479333982; called by muse, mutect2, varscan2
- DEPTOR | c.665G>C p.R222P | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV53815248; called by muse, mutect2, varscan2
- GAD2 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1414985700; called by muse, mutect2, varscan2
- IL13RA1 | c.828C>T p.Y276= | Splice Region (SNP) | VAF 10/86 reads (12%) | catalogued as rs747651648, COSV100861730; called by muse, mutect2
- KMT2C | c.11080C>G p.P3694A | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as COSV51428743; called by muse, mutect2
- MYBPC3 | c.2307C>T p.I769= | Splice Region (SNP) | VAF 16/176 reads (9%) | catalogued as rs775491112; called by muse, mutect2
- NEFH | c.319C>A p.R107S | Missense Mutation (SNP) | VAF 13/339 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs868037143; called by muse, mutect2
- RNF180 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 38/267 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs1388453815; called by muse, mutect2, varscan2
- ROBO4 | c.1009G>A p.V337M | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.92); catalogued as rs140504916, COSV60625838; called by muse, mutect2, varscan2
- RTP2 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs780808305, COSV64078780; called by muse, mutect2, varscan2
- SLIT3 | c.4351G>A p.G1451R | Missense Mutation (SNP) | VAF 37/301 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286920576; called by muse, mutect2, varscan2
- AKAP8 | c.286A>G p.I96V | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2
- ANKS1B | c.745+1G>C p.X249_splice | Splice Site (SNP) | VAF 45/180 reads (25%) | called by muse, mutect2, varscan2
- AOC1 | c.764A>G p.D255G | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ATRX | c.6045G>T p.E2015D | Missense Mutation (SNP) | VAF 40/383 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- BRWD3 | c.1708A>T p.N570Y | Missense Mutation (SNP) | VAF 58/542 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CASKIN1 | c.769G>C p.A257P | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM47C | c.287A>C p.K96T | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- GRK1 | c.1218C>G p.H406Q | Missense Mutation (SNP) | VAF 15/274 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- HBE1 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 19/327 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- INTS3 | c.1410-2A>G p.X470_splice | Splice Site (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
- ITGAE | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAP3K4 | c.3251G>A p.G1084D | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MLLT10 | c.1203del p.G402Efs*10 | Frame Shift Del (DEL) | VAF 15/134 reads (11%) | called by mutect2, pindel, varscan2
- MTARC1 | c.79G>C p.A27P | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PATJ | c.4092T>G p.I1364M | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2
- PRELID3B | c.291+2T>A p.X97_splice | Splice Site (SNP) | VAF 26/229 reads (11%) | called by muse, mutect2, varscan2
- PTPN14 | c.1235_1240dup p.N412_L413dup | In Frame Ins (INS) | VAF 36/290 reads (12%) | called by mutect2, varscan2
- PYGL | c.2012G>A p.G671D | Missense Mutation (SNP) | VAF 71/362 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RNGTT | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- SERPINE1 | c.1134C>G p.D378E | Missense Mutation (SNP) | VAF 75/531 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SETDB1 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 34/279 reads (12%) | called by muse, mutect2, varscan2
- SLC35G2 | c.195_199del p.R66Ffs*19 | Frame Shift Del (DEL) | VAF 24/143 reads (17%) | called by mutect2, pindel, varscan2
- VAT1L | c.500C>A p.T167K | Missense Mutation (SNP) | VAF 54/588 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2
- XPNPEP1 | c.1742dup p.N581Kfs*13 | Frame Shift Ins (INS) | VAF 44/264 reads (17%) | called by mutect2, pindel, varscan2
- ZNF546 | c.717C>G p.H239Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF99 | c.806C>A p.S269Y | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.998); called by muse, mutect2
- ABCA12 | c.231C>T p.D77= | Silent (SNP) | VAF 117/401 reads (29%) | catalogued as COSV55953320; called by muse, mutect2, varscan2
- ALS2CL | c.510G>T p.L170= | Silent (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2, varscan2
- CASP9 | c.225C>T p.S75= | Silent (SNP) | VAF 52/383 reads (14%) | called by muse, mutect2, varscan2
- CDH10 | c.2286C>T p.Y762= | Silent (SNP) | VAF 69/288 reads (24%) | catalogued as rs775096429, COSV52580162; called by muse, varscan2
- CROCC2 | c.2703G>A p.Q901= | Silent (SNP) | VAF 98/353 reads (28%) | called by muse, mutect2, varscan2
- EIF5 | c.1053C>T p.I351= | Silent (SNP) | VAF 42/212 reads (20%) | called by muse, mutect2, varscan2
- FAAH2 | c.1348T>C p.L450= | Silent (SNP) | VAF 102/581 reads (18%) | called by muse, varscan2
- FLT1 | c.3114T>C p.I1038= | Silent (SNP) | VAF 28/537 reads (5%) | catalogued as COSV56719014; called by muse, mutect2
- INPP5B | c.807G>A p.G269= (on ENST00000373023; = p.G189= on NM_005540.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 29/513 reads (6%) | called by muse, mutect2
- JMJD1C | c.1848A>T p.R616= | Silent (SNP) | VAF 82/193 reads (42%) | called by muse, mutect2, varscan2
- MC2R | c.306C>T p.A102= | Silent (SNP) | VAF 45/879 reads (5%) | catalogued as rs750855000; called by muse, mutect2
- OR6M1 | c.297A>G p.T99= | Silent (SNP) | VAF 46/339 reads (14%) | called by muse, mutect2, varscan2
- PLCB4 | c.1560T>G p.L520= | Silent (SNP) | VAF 34/327 reads (10%) | catalogued as rs1446914090; called by muse, mutect2, varscan2
- PLPPR3 | c.1428G>A p.P476= (on ENST00000520876 / NM_001270366.2; = p.P504= on NM_024888.2) | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs546087828; called by muse, mutect2, varscan2
- SAMM50 | c.423C>T p.G141= | Silent (SNP) | VAF 21/105 reads (20%) | called by muse, mutect2, varscan2
- TOMM20L | c.270C>T p.H90= | Silent (SNP) | VAF 26/124 reads (21%) | called by mutect2, varscan2
- WWC3 | c.789G>A p.T263= | Silent (SNP) | VAF 30/280 reads (11%) | catalogued as rs146879840; called by muse, mutect2, varscan2
- ZDBF2 | c.5874A>G p.R1958= | Silent (SNP) | VAF 10/309 reads (3%) | called by muse, mutect2
- ZER1 | c.1783T>C p.L595= | Silent (SNP) | VAF 24/172 reads (14%) | catalogued as rs751844625; called by muse, mutect2, varscan2
- ZNF552 | c.624A>G p.G208= | Silent (SNP) | VAF 44/190 reads (23%) | catalogued as rs764162166, COSV66971840, COSV66971977; called by muse, varscan2
- APLN | c.*81T>C | 3'UTR (SNP) | VAF 78/804 reads (10%) | called by muse, mutect2
- DMAC2 | c.18+425G>A | Intron (SNP) | VAF 40/183 reads (22%) | called by muse, mutect2, varscan2
- FAM3A | c.385+13G>T | Intron (SNP) | VAF 44/413 reads (11%) | called by muse, mutect2, varscan2
- NSG2 | c.*106G>A | 3'UTR (SNP) | VAF 34/163 reads (21%) | catalogued as rs752396473, COSV100292735; called by muse, mutect2, varscan2
- SLC39A7 | c.-57A>C | 5'UTR (SNP) | VAF 146/458 reads (32%) | called by muse, mutect2, varscan2
